Somatic mutation profile of tumor specimen TCGA-GN-A4U8-06A (aliquot TCGA-GN-A4U8-06A-11D-A32N-08) from TCGA case TCGA-GN-A4U8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.8 years (20,003 days).
Specimen TCGA-GN-A4U8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 285f36a8-b492-4143-9276-bce2409a18a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A4U8-10B (Blood Derived Normal), aliquot TCGA-GN-A4U8-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6311f680-9f0b-4e3f-98ed-223eafeaefac

The open-access MAF lists 469 somatic variants for this specimen: 315 protein-altering or splice-affecting, 141 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 141, Nonsense Mutation 23, Intron 7, RNA 3, Splice Site 3, Nonstop Mutation 2, Translation Start Site 2, Splice Region 1, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 160/531 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs864321714, CM100194, COSV59248770; ClinVar: pathogenic; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DNAH8 | c.7981C>T p.R2661* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs149070832; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs1554898053, CM981668, COSV64289438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100429208; called by muse, mutect2, varscan2
- ABL1 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100583576; called by muse, mutect2, varscan2
- ABL1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59336188, COSV59337423; called by muse, mutect2, varscan2
- ADAM22 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716087; called by muse, mutect2, varscan2
- ADAMTS2 | c.2450C>T p.T817I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV52366740; called by muse, mutect2, varscan2
- ADGRA1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101192646; called by muse, mutect2, varscan2
- ADPRHL1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1276297316, COSV100733376; called by muse, mutect2, varscan2
- ADPRHL1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749463598, COSV100215104; called by muse, mutect2, varscan2
- AHCTF1 | c.590T>C p.V197A (on ENST00000366508; = p.V171A on NM_015446.5) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV100403261; called by muse, mutect2, varscan2
- AKR1C4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99578532; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99782367; called by muse, mutect2, varscan2
- ARHGAP20 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV99503320; called by muse, mutect2, varscan2
- ARHGAP33 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV99137669; called by muse, mutect2, varscan2
- ARHGEF11 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 65/360 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs140673049; called by muse, mutect2, varscan2
- ARHGEF4 | c.494A>T p.Y165F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV100387701; called by muse, mutect2, varscan2
- ARMC4 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV53469166; called by muse, mutect2, varscan2
- ATP8B1 | c.3655G>A p.D1219N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs753339861, COSV99376931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAAT | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs773128969, COSV52287359; called by muse, mutect2, varscan2
- BATF3 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs925093445, COSV99695930; called by muse, mutect2, varscan2
- BEST2 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.111); catalogued as COSV99244280; called by muse, mutect2, varscan2
- BFSP2 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100183590; called by muse, mutect2, varscan2
- BICD1 | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.551); catalogued as COSV99862085; called by muse, mutect2, varscan2
- C19orf44 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201997646, COSV99550057; called by muse, mutect2, varscan2
- C1orf116 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 154/382 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1169369382, COSV100847893; called by muse, mutect2, varscan2
- CABS1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV56733618, COSV56734003; called by muse, mutect2, varscan2
- CACNG7 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 77/244 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1331412218, COSV99711880; called by muse, mutect2, varscan2
- CATSPER1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100375699; called by muse, mutect2, varscan2
- CCBE1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs267605221, COSV101232787; called by muse, varscan2
- CCDC141 | c.2527C>A p.L843M | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836351; called by muse, mutect2, varscan2
- CCDC93 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as rs770401792, COSV60123381; called by muse, mutect2, varscan2
- CCER1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 166/615 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV100726953; called by muse, mutect2, varscan2
- CCNQ | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV52343956; called by muse, mutect2, varscan2
- CCT8L2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100742594; called by muse, mutect2, varscan2
- CDH9 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 63/219 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as rs531958842, COSV50256671, COSV99162875; called by muse, mutect2, varscan2
- CFAP47 | c.322C>T p.H108Y | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.955); catalogued as COSV99934577; called by muse, mutect2, varscan2
- CFAP47 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 48/86 reads (56%) | catalogued as COSV52890354; called by muse, mutect2, varscan2
- CHAF1B | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100023398; called by muse, mutect2, varscan2
- CHD2 | c.5469G>A p.W1823* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV101244837; called by muse, mutect2, varscan2
- CHD8 | c.896C>T p.P299L (on ENST00000646647 / NM_001170629.2; = p.P20L on NM_020920.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV101303061; called by muse, mutect2, varscan2
- CHRNA2 | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as COSV53558185; called by muse, mutect2, varscan2
- CLEC18B | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as rs745534108, COSV100375722; called by muse, mutect2, varscan2
- CLIP3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs753796234, COSV100859284; called by muse, mutect2, varscan2
- CNTN5 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV99672061, COSV99674012; called by muse, mutect2
- COL24A1 | c.5038C>T p.H1680Y | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV100993017; called by muse, mutect2, varscan2
- CPNE4 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1330733089, COSV70192470; called by muse, mutect2, varscan2
- CRB1 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.907); catalogued as rs1461964160, COSV66335623; called by muse, mutect2, varscan2
- CREB3L1 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV99914870; called by muse, mutect2, varscan2
- CRISP2 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV59257021; called by muse, mutect2, varscan2
- CSMD2 | c.10082C>T p.S3361L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs750437715, COSV53885364; called by muse, mutect2, varscan2
- CSMD2 | c.5237G>A p.R1746K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs372050861, COSV99587088; called by muse, mutect2, varscan2
- CTHRC1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 46/277 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100372937; called by muse, mutect2, varscan2
- CTTN | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs773345646, COSV100097281, COSV57231053; called by muse, mutect2, varscan2
- CXADR | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV99515079; called by muse, mutect2, varscan2
- CYBB | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as COSV101059696; called by muse, mutect2, varscan2
- CYP2C9 | c.78A>T p.R26S | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV99582393; called by muse, mutect2, varscan2
- CYYR1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100176626; called by muse, mutect2, varscan2
- DCAF4L1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1224359974, COSV60787139; called by muse, mutect2, varscan2
- DCAF8L1 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1215819339, COSV101491415; called by muse, mutect2, varscan2
- DCC | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as rs752208238, COSV100498662; called by muse, mutect2, varscan2
- DDIAS | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV100231060; called by muse, mutect2, varscan2
- DLL4 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99989666; called by muse, mutect2, varscan2
- DNAAF1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs748803341, COSV99550290; called by muse, mutect2, varscan2
- DNAAF6 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as rs865950026, COSV100314442; called by muse, mutect2, varscan2
- DNAH11 | c.3666G>A p.W1222* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100177847; called by muse, mutect2, varscan2
- DNAH5 | c.13553C>T p.T4518I | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV54247068; called by muse, mutect2, varscan2
- DNAH5 | c.11317G>A p.G3773R | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99446160; called by muse, mutect2, varscan2
- DNAH9 | c.4314G>T p.K1438N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as COSV52376740, COSV99304645; called by muse, mutect2, varscan2
- DPY19L2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs748677303, COSV61042189; called by muse, mutect2, varscan2
- DPY19L2 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV100116587; called by mutect2, varscan2
- DRC7 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV100395428; called by muse, mutect2, varscan2
- DSC2 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as COSV99199530; called by muse, mutect2, varscan2
- DSCAM | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV101259355; called by muse, mutect2, varscan2
- DSE | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs1478402459, COSV100528389; called by muse, mutect2, varscan2
- DYTN | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV101510811, COSV101510895; called by muse, mutect2, varscan2
- ECT2 | c.1489_1491del p.E497del (on ENST00000392692 / NM_001349098.2; = p.E466del on NM_018098.6 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs1389234362; called by pindel, varscan2
- EFR3A | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs765532571, COSV99602561; called by muse, varscan2
- ELL2 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 73/313 reads (23%) | catalogued as COSV99427271; called by muse, mutect2, varscan2
- EMB | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100296688; called by muse, mutect2, varscan2
- ENAM | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.767); catalogued as COSV68536338; called by muse, mutect2, varscan2
- ESF1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV99176282; called by muse, mutect2, varscan2
- EXTL3 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as COSV99593806, COSV99594202, COSV99594299; called by muse, mutect2, varscan2
- F13B | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100803216; called by muse, mutect2, varscan2
- F2RL3 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99935145; called by muse, mutect2, varscan2
- FAM120C | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100069683; called by muse, mutect2, varscan2
- FAM181A | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1225601342, COSV50887920, COSV99967797; called by muse, mutect2, varscan2
- FAM53B | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99784845; called by muse, mutect2, varscan2
- FAT3 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.876); catalogued as COSV99963016; called by muse, mutect2, varscan2
- FAT3 | c.3521A>C p.D1174A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99963022; called by muse, mutect2, varscan2
- FGD5 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV99547504; called by muse, mutect2, varscan2
- FGD6 | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.086); catalogued as COSV100676420; called by muse, mutect2, varscan2
- FGFR2 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60641276; called by muse, mutect2, varscan2
- FLCN | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99550189; called by muse, mutect2, varscan2
- FLG | c.11173G>T p.G3725* | Nonsense Mutation (SNP) | VAF 184/846 reads (22%) | catalogued as COSV100910904; called by muse, mutect2, varscan2
- FOXD4L3 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.265); catalogued as COSV100730988; called by muse, mutect2, varscan2
- FOXG1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100486588; called by muse, mutect2, varscan2
- FPR2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs775137302, COSV100389167; called by muse, mutect2, varscan2
- FPR3 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs1379995512, COSV59330775; called by muse, mutect2, varscan2
- FSHR | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as COSV58623355, COSV58638397; called by muse, mutect2, varscan2
- GBA3 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs267600127, COSV101545483; called by muse, mutect2, varscan2
- GEMIN7 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541537; called by muse, mutect2, varscan2
- GHDC | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV100054553; called by muse, mutect2, varscan2
- GHR | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs577421663, COSV99039098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GK2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs776385662, COSV62625914, COSV62628380; called by muse, mutect2, varscan2
- GLDC | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as COSV58681146; called by muse, mutect2, varscan2
- GPC5 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65599455; called by muse, mutect2, varscan2
- GPC5 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.937); catalogued as rs1199153943, COSV65585488, COSV65605963; called by muse, mutect2, varscan2
- GRIA1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs377273074; called by muse, mutect2, varscan2
- GRIA2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV52396976; called by muse, mutect2, varscan2
- GRIK1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100516080, COSV58712422; called by muse, mutect2, varscan2
- GRIN3B | c.1879C>T p.L627F | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312268; called by muse, mutect2, varscan2
- HCFC1 | c.2666C>T p.T889I | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV60072504; called by muse, mutect2, varscan2
- HEPACAM2 | c.1043C>T p.S348L (on ENST00000394468 / NM_001039372.4; = p.S336L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV100506352; called by muse, mutect2, varscan2
- HESX1 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99072772, COSV99907682; called by muse, mutect2, varscan2
- HNF4A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.444); catalogued as rs748452860, COSV57382487; called by muse, mutect2, varscan2
- HSD17B12 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99550435; called by muse, mutect2, varscan2
- HSP90AB1 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765842603, COSV62335375; called by muse, mutect2, varscan2
- HTR6 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.175); catalogued as rs764734222, COSV99229967; called by muse, mutect2, varscan2
- IDUA | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113974, COSV99925757; called by muse, mutect2, varscan2
- IDUA | c.1791G>C p.R597S | Missense Mutation (SNP) | VAF 83/291 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV99925760; called by muse, mutect2, varscan2
- IMMP2L | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.43); catalogued as COSV100068609; called by muse, mutect2, varscan2
- INSL6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1381072524, COSV67563289; called by muse, mutect2, varscan2
- KANSL1 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs777494240, COSV52264702, COSV52267293, COSV99294174; called by muse, mutect2, varscan2
- KAT6A | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268928913, COSV99704565; called by muse, mutect2, varscan2
- KCNQ2 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765394232, COSV100609921; called by muse, mutect2, varscan2
- KCNT2 | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99651676, COSV99652135; called by muse, mutect2, varscan2
- KLK12 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs925148577, COSV51576518; called by muse, mutect2, varscan2
- L2HGDH | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910116; called by muse, mutect2, varscan2
- LAMA5 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.817); catalogued as rs774112548, COSV99438513; called by muse, mutect2, varscan2
- LAYN | c.646G>A p.E216K (on ENST00000375615 / NM_001258390.1; = p.E208K on NM_178834.5) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199779220, COSV65104855; called by muse, mutect2, varscan2
- LBP | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs1437019495, COSV99460522; called by muse, mutect2, varscan2
- LMX1A | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54217594, COSV99671818; called by muse, mutect2, varscan2
- LRFN2 | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV57824961; called by muse, mutect2, varscan2
- LRP1 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 37/179 reads (21%) | catalogued as COSV99674892, COSV99675884; called by muse, mutect2, varscan2
- LRRC37B | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100496083; called by muse, mutect2, varscan2
- LRRC37B | c.2408C>T p.T803I | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1159106571, COSV100496084; called by muse, mutect2, varscan2
- LRRC7 | c.4115C>A p.P1372Q (on ENST00000651989 / NM_001370785.2; = p.P1292Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50532303, COSV99225054; called by muse, mutect2, varscan2
- LRRC8D | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100487073; called by muse, mutect2, varscan2
- LRRN3 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57824945; called by muse, mutect2, varscan2
- LTB4R2 | c.1054A>G p.R352G (on ENST00000528054; = p.R321G on NM_019839.5) | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as COSV99350550; called by muse, mutect2, varscan2
- MAP3K2 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789261, COSV61293173; called by muse, mutect2, varscan2
- MARCKSL1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as COSV100269512; called by muse, mutect2, varscan2
- MARCO | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100503253, COSV59053977; called by muse, mutect2
- MBD3 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99336883; called by muse, mutect2, varscan2
- MCF2 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV58481808; called by muse, mutect2, varscan2
- MDC1 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV100902656; called by muse, mutect2, varscan2
- MED13 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV101180821; called by muse, mutect2, varscan2
- MFSD4A | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901456; called by muse, mutect2
- MGAM | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 92/176 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as rs782295291, COSV71885410; called by muse, mutect2, varscan2
- MIDEAS | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99678661; called by muse, mutect2, varscan2
- MROH7 | c.1698C>T p.A566= | Splice Region (SNP) | VAF 37/196 reads (19%) | catalogued as COSV100273090; called by muse, mutect2, varscan2
- MSH4 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as COSV99590961; called by muse, mutect2, varscan2
- MSR1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026742; called by muse, mutect2, varscan2
- MTMR14 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | catalogued as rs750945377, COSV56004664; called by muse, mutect2, varscan2
- MUC16 | c.32756C>T p.S10919F | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV67505033; called by muse, mutect2, varscan2
- MUC4 | c.13778G>A p.R4593Q (on ENST00000463781 / NM_018406.7; = p.R357Q on NM_004532.6) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs372065699, COSV100203974; called by muse, mutect2, varscan2
- MUC5B | c.12908G>A p.R4303K | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV71594700; called by muse, mutect2, varscan2
- MYH2 | c.4801G>A p.E1601K | Missense Mutation (SNP) | VAF 60/261 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs1302912256, COSV99819498; called by muse, mutect2, varscan2
- MYH4 | c.2299-1G>A p.X767_splice | Splice Site (SNP) | VAF 36/157 reads (23%) | catalogued as COSV55111820, COSV99700555; called by muse, mutect2, varscan2
- MYH7 | c.5404C>A p.Q1802K | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100805791; called by muse, mutect2, varscan2
- MYO3A | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs56403976, COSV56324596; called by muse, mutect2, varscan2
- NCAM2 | c.1441A>T p.I481L | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1214721154, COSV99521767; called by muse, mutect2, varscan2
- NCKAP5 | c.4173C>A p.F1391L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100490552; called by muse, mutect2, varscan2
- NEBL | c.2282C>A p.P761Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV101009123; called by muse, mutect2, varscan2
- NEBL | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 83/317 reads (26%) | catalogued as COSV101009124; called by muse, mutect2, varscan2
- NETO1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100198331; called by muse, mutect2, varscan2
- NLRC5 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as rs546634408, COSV99346676; called by muse, mutect2, varscan2
- NLRC5 | c.5510C>T p.P1837L | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV52658449; called by muse, mutect2, varscan2
- NLRP8 | c.2807T>G p.L936R | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99404851; called by muse, mutect2
- NOP2 | c.665C>T p.P222L (on ENST00000322166 / NM_001258308.2; = p.P218L on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as rs749124800, COSV100444729; called by muse, mutect2, varscan2
- NOP2 | c.664C>T p.P222S (on ENST00000322166 / NM_001258308.2; = p.P218S on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1323962431, COSV100444731; called by muse, mutect2, varscan2
- NPAP1 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV61508487, COSV61509591; called by muse, mutect2, varscan2
- NPM1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs1363897984, COSV99742062; called by muse, mutect2, varscan2
- NRXN3 | c.1733G>A p.G578E (on ENST00000335750 / NM_001330195.2; = p.G205E on NM_004796.6) | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867506842, COSV100201560; called by muse, mutect2, varscan2
- NRXN3 | c.2189C>T p.S730F (on ENST00000335750 / NM_001330195.2; = p.S357F on NM_004796.6) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100201562; called by muse, mutect2, varscan2
- NTF3 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100451069; called by muse, mutect2, varscan2
- NTN4 | c.1812G>A p.M604I | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV100643701; called by muse, mutect2, varscan2
- NUFIP1 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100997971; called by muse, mutect2, varscan2
- OR10A6 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100564247; called by muse, mutect2, varscan2
- OR10H4 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59061375; called by muse, mutect2, varscan2
- OR10T2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100554853; called by muse, mutect2, varscan2
- OR2J2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs866648498, COSV65848372; called by muse, mutect2, varscan2
- OR4K1 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV53458913, COSV53460428; called by muse, mutect2
- OR51G1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs200001303; called by muse, mutect2, varscan2
- OR8H1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 125/509 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs867315106, COSV57293250; called by muse, mutect2, varscan2
- OR9K2 | c.928C>T p.P310S (on ENST00000305377; = p.P288S on NM_001005243.1) | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs763519211, COSV59531408; called by muse, mutect2, varscan2
- OTOP1 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs758517080, COSV56390457; called by muse, mutect2, varscan2
- PAPLN | c.1391C>T p.S464F (on ENST00000554301; = p.S437F on NM_173462.4) | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV99389252; called by muse, mutect2, varscan2
- PARP8 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV99890337; called by muse, mutect2, varscan2
- PCDH1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 46/170 reads (27%) | catalogued as COSV99745654; called by muse, mutect2, varscan2
- PCDH15 | c.2284C>T p.L762F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.972); catalogued as COSV100216998; called by muse, mutect2, varscan2
- PCDH8 | c.2006G>A p.G669E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131308; called by muse, mutect2, varscan2
- PCDHB8 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 81/594 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV50795656; called by muse, mutect2, varscan2
- PCDHB9 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.089); catalogued as rs371641241; called by muse, mutect2, varscan2
- PCDHGA4 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1211736119, COSV99533020; called by muse, mutect2, varscan2
- PCLO | c.4133C>T p.P1378L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61645865; called by muse, mutect2, varscan2
- PFKFB4 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | PolyPhen possibly damaging (0.848); catalogued as rs761570064, COSV99219404; called by muse, mutect2, varscan2
- PHF21B | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV100503598; called by muse, mutect2, varscan2
- PI16 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs200144943, COSV101010157; called by muse, mutect2, varscan2
- PKHD1L1 | c.2738G>A p.G913E | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs866551110, COSV65738761, COSV65751132; called by muse, mutect2, varscan2
- PKHD1L1 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as COSV101005596; called by muse, mutect2, varscan2
- PLAT | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99535035; called by muse, mutect2, varscan2
- PLB1 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100214933; called by muse, mutect2, varscan2
- PLCG2 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as COSV63867589, COSV63879061; called by muse, mutect2, varscan2
- PLXNB1 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.477); catalogued as COSV99602449; called by muse, mutect2, varscan2
- POLE | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 167/410 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100265636; called by muse, mutect2, varscan2
- POLR3B | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs757194712, COSV57276666; called by muse, varscan2
- PPARGC1A | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1438248533, COSV99337430; called by muse, mutect2, varscan2
- PPP2R1B | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100231936; called by muse, mutect2, varscan2
- PPP2R1B | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100231939; called by muse, mutect2, varscan2
- PPWD1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV99731149; called by muse, mutect2, varscan2
- PPWD1 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as rs1430916098, COSV99731101; called by muse, mutect2, varscan2
- PRDM15 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200961793, COSV99519509; called by muse, mutect2, varscan2
- PRKAA2 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV100982762; called by muse, mutect2, varscan2
- PTPRN | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99833775; called by muse, mutect2, varscan2
- RASGRP1 | c.2392T>C p.*798Qext*4 | Nonstop Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100171802; called by muse, mutect2, varscan2
- RBBP8 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV100507151; called by muse, mutect2, varscan2
- RBL1 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100726915; called by muse, mutect2, varscan2
- RBL1 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100726916; called by muse, mutect2, varscan2
- RGS7 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1316436060, COSV58564390; called by muse, mutect2, varscan2
- RIMS2 | c.1532C>T p.S511L (on ENST00000666250 / NM_001348490.2; = p.S319L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650842; called by muse, mutect2, varscan2
- RIMS2 | c.2382G>A p.W794* (on ENST00000666250 / NM_001348490.2; = p.W602* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 93/190 reads (49%) | catalogued as COSV51656385, COSV99163567; called by muse, mutect2, varscan2
- RNF133 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV57357525; called by muse, mutect2, varscan2
- RPP14 | c.355A>G p.R119G | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99916669; called by muse, mutect2, varscan2
- RPP40 | c.1090T>A p.*364Kext*65 | Nonstop Mutation (SNP) | VAF 30/113 reads (27%) | catalogued as rs759328874, COSV100123915; called by muse, mutect2, varscan2
- SCN10A | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101479273; called by muse, mutect2, varscan2
- SCN4A | c.1602G>A p.M534I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs772275347, COSV101438354; called by muse, varscan2
- SERPINA10 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs757589959, COSV100003671; called by muse, mutect2, varscan2
- SERPINB6 | c.1117C>T p.P373S (on ENST00000612421 / NM_001271823.2; = p.P354S on NM_004568.6) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177423; called by muse, mutect2, varscan2
- SESN2 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99455472; called by muse, mutect2, varscan2
- SHBG | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 146/530 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99352135; called by muse, mutect2, varscan2
- SIGLEC5 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs1214228622, COSV99707224; called by muse, mutect2, varscan2
- SLC1A1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV52057965; called by muse, mutect2, varscan2
- SLC2A10 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV63715794; called by muse, mutect2, varscan2
- SLC37A4 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100421480; called by muse, mutect2, varscan2
- SLC38A4 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs1323663754, COSV99872525; called by muse, mutect2, varscan2
- SLC4A8 | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV101493098; called by muse, mutect2, varscan2
- SNAPC4 | c.1790C>T p.S597F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); catalogued as rs749965458, COSV100046907; called by muse, varscan2
- SNED1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122346; called by muse, mutect2, varscan2
- SNED1 | c.1892G>A p.G631D | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100122348, COSV100123421; called by muse, mutect2, varscan2
- SORL1 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753082593, COSV52754564; called by muse, mutect2, varscan2
- SPACA4 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99613877; called by muse, mutect2, varscan2
- SPANXN3 | c.400T>A p.S134T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.916); catalogued as COSV100980773; called by muse, mutect2, varscan2
- SPIRE1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100563425; called by muse, mutect2, varscan2
- SPOCK3 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs1211547956, COSV62724971; called by muse, mutect2, varscan2
- SPTLC3 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs1280035776, COSV100982954; called by muse, mutect2, varscan2
- ST3GAL5 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV60385177, COSV60386981; called by muse, mutect2, varscan2
- ST8SIA5 | c.569+1G>A p.X190_splice | Splice Site (SNP) | VAF 25/111 reads (23%) | catalogued as COSV100164562; called by muse, mutect2, varscan2
- STXBP5L | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99872540; called by muse, mutect2, varscan2
- SUSD1 | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100813199; called by muse, mutect2, varscan2
- SV2B | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57698501; called by muse, mutect2, varscan2
- SYTL5 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99936948; called by muse, mutect2, varscan2
- TAOK1 | c.2521C>T p.R841W | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs759310874, COSV99913652; called by muse, mutect2, varscan2
- TAS2R14 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs948987950, COSV101114332; called by muse, mutect2
- TAS2R50 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as rs202189587, COSV67859279; called by muse, mutect2, varscan2
- TCERG1 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV99694510; called by muse, mutect2, varscan2
- TCIRG1 | c.1460G>A p.W487* | Nonsense Mutation (SNP) | VAF 55/261 reads (21%) | catalogued as COSV99693174; called by muse, mutect2, varscan2
- TCIRG1 | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 56/257 reads (22%) | catalogued as COSV99693176; called by muse, mutect2, varscan2
- TDRD5 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 208/446 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99675702; called by muse, mutect2, varscan2
- TENT5C | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101032824; called by muse, mutect2, varscan2
- TEX33 | c.353G>A p.G118E (on ENST00000381821 / NM_001163857.2; = p.G33E on NM_178552.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV101111477; called by muse, mutect2, varscan2
- THBS3 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 97/478 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100857511; called by muse, mutect2, varscan2
- THSD7B | c.4057G>A p.E1353K (on ENST00000272643; = p.E1351K on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs868441368, COSV55667658; called by muse, mutect2, varscan2
- TIMP2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99430218; called by muse, mutect2, varscan2
- TMEM132B | c.2549C>T p.P850L | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100168830; called by muse, mutect2, varscan2
- TMEM171 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 98/402 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV55129429, COSV99824884; called by muse, mutect2, varscan2
- TMPRSS11B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100219270; called by muse, mutect2, varscan2
- TMUB2 | c.160C>T p.L54F (on ENST00000538716 / NM_001353177.2; = p.L34F on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV100116054; called by muse, mutect2, varscan2
- TNS1 | c.3817G>A p.G1273S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs1413618010, COSV50731300, COSV99410044; called by muse, mutect2, varscan2
- TRAJ28 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs774453593; called by muse, varscan2
- TRAPPC9 | c.2586C>G p.Y862* | Nonsense Mutation (SNP) | VAF 33/205 reads (16%) | catalogued as COSV101226896; called by muse, mutect2, varscan2
- TRAV8-4 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as rs761054257; called by muse, mutect2, varscan2
- TRIM49 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100315919; called by muse, mutect2, varscan2
- TSHZ1 | c.3206T>A p.I1069N (on ENST00000580243 / NM_001308210.2; = p.I1024N on NM_005786.6) | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100433457; called by muse, mutect2
- TSKS | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567740680, COSV55872583; called by muse, mutect2, varscan2
- TTC31 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99281976; called by muse, mutect2, varscan2
- TTN | c.28555G>A p.E9519K (on ENST00000591111; = p.E8592K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | PolyPhen probably damaging (0.994); catalogued as COSV60115852; called by muse, mutect2, varscan2
- TTN | c.17288G>A p.G5763E (on ENST00000591111; = p.G4836E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV100599057; called by muse, mutect2, varscan2
- TTN | c.12739G>A p.E4247K (on ENST00000591111; = p.E4201K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as rs746672079, COSV60169973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP2 | c.2351C>T p.T784I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99427339; called by muse, mutect2, varscan2
- TULP1 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs771156064, COSV100003957; called by muse, mutect2, varscan2
- UBE3C | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 43/176 reads (24%) | catalogued as rs560281237, COSV61956142; called by muse, mutect2, varscan2
- UBR5 | c.3854G>A p.R1285K | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99639772; called by muse, mutect2, varscan2
- UGT2B15 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 168/657 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as COSV57735622; called by muse, mutect2, varscan2
- UGT2B28 | c.401A>T p.K134M | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100158618; called by muse, mutect2, varscan2
- UNC13C | c.3239T>C p.V1080A | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99512987; called by muse, mutect2, varscan2
- USP29 | c.1707G>A p.M569I | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.047); catalogued as COSV99517801; called by muse, mutect2, varscan2
- UTP11 | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs1277933687, COSV100884870; called by muse, mutect2, varscan2
- VAT1L | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.777); catalogued as COSV56819745; called by muse, mutect2, varscan2
- VPS54 | c.1184T>G p.L395R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs1465979170, COSV99707847; called by muse, mutect2, varscan2
- VWA8 | c.2759-1G>A p.X920_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99863684; called by muse, mutect2, varscan2
- WDR38 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867400394, COSV100793802; called by muse, mutect2, varscan2
- WDR72 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs921714846, COSV100854286, COSV64741937; called by muse, mutect2, varscan2
- YTHDF3 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.515); catalogued as rs1454606619, COSV101572363; called by muse, mutect2, varscan2
- ZBED9 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV71729611; called by muse, mutect2, varscan2
- ZFHX3 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 57/230 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs758176150, COSV99195611; called by muse, mutect2, varscan2
- ZFHX4 | c.7864G>A p.E2622K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV50492398, COSV99258402; called by muse, mutect2, varscan2
- ZFYVE16 | c.2834C>T p.P945L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs1239887264, COSV100566248; called by muse, mutect2, varscan2
- ZNF142 | c.3329C>T p.P1110L (on ENST00000411696 / NM_001379660.1; = p.P910L on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/331 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1193279722, COSV101376909; called by muse, mutect2, varscan2
- ZNF468 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54697865; called by muse, mutect2, varscan2
- ZNF564 | c.870C>A p.F290L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV100213048, COSV59436102; called by muse, mutect2, varscan2
- ZNF608 | c.3386G>A p.R1129K | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as COSV100101193; called by muse, mutect2, varscan2
- ZNF611 | c.2098C>T p.H700Y | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100160101; called by muse, mutect2, varscan2
- ZNF615 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs760926442, COSV100943728; called by muse, mutect2, varscan2
- ZNF653 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201563028, COSV99542033; called by muse, mutect2, varscan2
- ZNF655 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV99401984; called by muse, mutect2, varscan2
- ZNF746 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV100502387; called by muse, mutect2, varscan2
- ZNF765 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV101125395; called by muse, mutect2, varscan2
- ZNF804B | c.2251G>C p.E751Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100302343, COSV100304552; called by muse, mutect2, varscan2
- IGKV5-2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC17 | c.6004G>A p.A2002T | Missense Mutation (SNP) | VAF 141/536 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDHB9 | c.2312C>T p.T771I | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCG5 | c.1419C>T p.P473= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99575209; called by muse, mutect2, varscan2
- ADGRA3 | c.2265G>A p.A755= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs745643517, COSV99293014; called by muse, mutect2, varscan2
- ADGRG4 | c.5541C>T p.I1847= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as COSV99794669; called by muse, mutect2, varscan2
- ADGRV1 | c.2301G>A p.L767= | Silent (SNP) | VAF 53/189 reads (28%) | catalogued as COSV101315583, COSV67979849; called by muse, mutect2, varscan2
- ALDH3B1 | c.448C>T p.L150= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99141721; called by muse, mutect2
- ALOX5AP | c.75C>T p.F25= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100996268, COSV66857642; called by muse, mutect2, varscan2
- ANAPC1 | c.717T>G p.V239= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV100594565; called by muse, mutect2, varscan2
- BATF3 | c.348C>T p.P116= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV99695933; called by muse, mutect2, varscan2
- BMERB1 | c.360C>T p.I120= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100252721; called by muse, mutect2, varscan2
- CACNA1H | c.1083C>T p.F361= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as rs763566127, COSV61990794; called by muse, varscan2
- CATSPER1 | c.777G>A p.G259= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100375697; called by muse, mutect2, varscan2
- CDH10 | c.2028G>A p.R676= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV100050436; called by muse, mutect2, varscan2
- CMKLR1 | c.555G>A p.G185= (on ENST00000312143 / NM_001142344.2; = p.G183= on NM_004072.3) | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV56436783; called by muse, mutect2, varscan2
- CRACD | c.2025C>T p.I675= | Silent (SNP) | VAF 42/168 reads (25%) | catalogued as rs749494821, COSV99948774; called by muse, mutect2, varscan2
- CRHR2 | c.141C>T p.I47= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV59268135; called by muse, mutect2
- CYFIP2 | c.2454C>T p.S818= (on ENST00000616178 / NM_001291722.2; = p.S793= on NM_014376.4) | Silent (SNP) | VAF 78/286 reads (27%) | catalogued as COSV100555868; called by muse, varscan2
- CYP2A13 | c.1176C>T p.F392= | Silent (SNP) | VAF 54/218 reads (25%) | catalogued as COSV100386666; called by muse, mutect2, varscan2
- DAW1 | c.579G>A p.A193= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as rs1172416364, COSV100005928; called by muse, mutect2, varscan2
- DCLK3 | c.231G>A p.G77= | Silent (SNP) | VAF 80/286 reads (28%) | catalogued as COSV69362749; called by muse, mutect2, varscan2
- DCN | c.391T>C p.L131= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs1329032870, COSV99271881; called by muse, mutect2, varscan2
- DCTN4 | c.249C>T p.L83= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV101437536; called by muse, mutect2, varscan2
- DDX46 | c.1158C>T p.S386= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV100844854; called by muse, mutect2, varscan2
- DISP2 | c.3778C>T p.L1260= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs1211889268, COSV99139763; called by muse, mutect2, varscan2
- DNAH17 | c.4755C>T p.S1585= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs780666100, COSV101101659; called by muse, mutect2, varscan2
- DNAH5 | c.10230G>A p.T3410= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as rs765000004, COSV54201418; called by muse, mutect2, varscan2
- DNAH5 | c.1491A>G p.Q497= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV99446163; called by muse, mutect2, varscan2
- DNAH9 | c.11130C>T p.F3710= | Silent (SNP) | VAF 57/221 reads (26%) | catalogued as COSV99304646; called by muse, mutect2, varscan2
- DSG1 | c.2691G>A p.R897= | Silent (SNP) | VAF 75/260 reads (29%) | catalogued as COSV99935661; called by muse, mutect2, varscan2
- DUOX2 | c.2733G>A p.S911= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs1032245274, COSV66532510; called by muse, mutect2, varscan2
- ENO1 | c.402C>T p.I134= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as rs369611743; called by muse, mutect2, varscan2
- ERICH6 | c.864C>T p.S288= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV99901429; called by muse, mutect2, varscan2
- ESRP1 | c.39G>A p.G13= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100619207; called by muse, mutect2, varscan2
- F5 | c.828G>C p.L276= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs1445433470, COSV100888971; called by muse, mutect2, varscan2
- FAM166B | c.402G>A p.K134= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs1333280892, COSV100770618; called by muse, mutect2, varscan2
- FAM47B | c.342G>A p.R114= | Silent (SNP) | VAF 46/98 reads (47%) | catalogued as COSV61455292; called by muse, mutect2, varscan2
- FAM71B | c.522C>T p.L174= | Silent (SNP) | VAF 69/320 reads (22%) | catalogued as COSV100261917; called by muse, mutect2, varscan2
- FBXW8 | c.270C>T p.N90= (on ENST00000309909; = p.N128= on NM_012174.1) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs1019739296, COSV99997508; called by muse, mutect2, varscan2
- FCER1A | c.762C>T p.P254= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100929248; called by muse, mutect2, varscan2
- GPC6 | c.1257G>A p.E419= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs1370171797, COSV100988169, COSV65522564; called by muse, mutect2, varscan2
- GRIN3A | c.1392C>T p.F464= | Silent (SNP) | VAF 83/334 reads (25%) | catalogued as COSV62451106; called by muse, mutect2, varscan2
- GTF2F1 | c.1314C>T p.P438= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs1447452407, COSV99831692; called by muse, mutect2, varscan2
- HAL | c.1563C>T p.S521= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99701237; called by muse, mutect2, varscan2
- HECW1 | c.1845G>A p.E615= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV67839703; called by muse, mutect2
- HECW2 | c.3366G>A p.G1122= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1459492598, COSV99646177; called by muse, mutect2, varscan2
- HOXA6 | c.63C>T p.F21= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs776113892, COSV56072445, COSV56075013; called by muse, mutect2, varscan2
- HTRA4 | c.1404G>A p.L468= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100205635; called by muse, mutect2, varscan2
- IFNA4 | c.432G>A p.R144= | Silent (SNP) | VAF 129/492 reads (26%) | catalogued as COSV101427022; called by muse, mutect2, varscan2
- IGBP1P2 | c.627G>A p.E209= | Silent (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- IGHV3-20 | c.291C>T p.S97= | Silent (SNP) | VAF 124/458 reads (27%) | called by muse, mutect2, varscan2
- IL18 | c.144A>T p.I48= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV99737043; called by muse, mutect2, varscan2
- KCNA7 | c.684C>T p.L228= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV99671848; called by muse, mutect2, varscan2
- KCNJ8 | c.660C>T p.I220= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV99557415; called by muse, mutect2, varscan2
- KCNT2 | c.633C>T p.F211= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as COSV54091232; called by muse, mutect2, varscan2
- KLC1 | c.432G>A p.E144= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV99871269; called by muse, mutect2, varscan2
- KLF8 | c.891C>T p.I297= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV100808141; called by muse, mutect2, varscan2
- KRT6A | c.1248G>A p.G416= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV58107372; called by muse, mutect2, varscan2
- LINGO4 | c.282C>T p.N94= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV100561825, COSV59091923; called by muse, mutect2, varscan2
- MCPH1 | c.2169T>C p.I723= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as COSV100290705; called by muse, mutect2, varscan2
- MEI1 | c.687C>T p.S229= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100299711; called by muse, mutect2, varscan2
- MET | c.1902C>T p.F634= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs772450441, COSV100577063; ClinVar: likely benign; called by muse, mutect2, varscan2
- MIDEAS | c.2847C>T p.I949= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99678662; called by muse, mutect2, varscan2
- MOG | c.126G>A p.R42= | Silent (SNP) | VAF 86/377 reads (23%) | catalogued as COSV100972968; called by muse, mutect2, varscan2
- MPDZ | c.3624C>T p.I1208= | Silent (SNP) | VAF 74/251 reads (29%) | catalogued as rs371166354; called by muse, mutect2, varscan2
- MUC16 | c.23445C>T p.F7815= | Silent (SNP) | VAF 59/219 reads (27%) | catalogued as COSV67448072; called by muse, mutect2, varscan2
- MYH2 | c.1476C>T p.F492= | Silent (SNP) | VAF 77/268 reads (29%) | catalogued as COSV55433687; called by muse, mutect2, varscan2
- MYO7B | c.5676G>A p.R1892= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100264296; called by muse, mutect2, varscan2
- MYOCD | c.2382C>T p.I794= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as COSV100591551, COSV58509984; called by muse, mutect2, varscan2
- NLGN2 | c.1110G>A p.Q370= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as COSV100080849; called by muse, mutect2, varscan2
- NLGN4X | c.1065C>T p.I355= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV99320379; called by muse, mutect2, varscan2
- NLRC4 | c.609C>T p.L203= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV61592692; called by muse, mutect2, varscan2
- NLRP14 | c.2706G>A p.L902= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as rs1281774736, COSV100204666; called by muse, mutect2, varscan2
- NMS | c.461G>A p.*154= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100966560; called by muse, mutect2, varscan2
- NPAP1 | c.3156C>T p.F1052= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV61510234; called by muse, mutect2, varscan2
- NPC1L1 | c.3249G>A p.L1083= | Silent (SNP) | VAF 43/177 reads (24%) | catalogued as COSV99203006; called by muse, mutect2, varscan2
- NTNG1 | c.306C>T p.P102= | Silent (SNP) | VAF 96/407 reads (24%) | catalogued as COSV53974790; called by muse, mutect2, varscan2
- NTRK3 | c.2241C>T p.F747= (on ENST00000360948 / NM_001012338.2; = p.F733= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100712365; called by muse, mutect2, varscan2
- OR10G9 | c.768C>T p.F256= | Silent (SNP) | VAF 54/214 reads (25%) | catalogued as COSV66685830; called by muse, mutect2, varscan2
- OR4D2 | c.690G>A p.G230= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV101613845; called by muse, mutect2, varscan2
- OR5T2 | c.882C>T p.I294= | Silent (SNP) | VAF 64/238 reads (27%) | catalogued as rs748956980, COSV57590322; called by muse, mutect2, varscan2
- OTOP1 | c.1107C>T p.I369= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as COSV99587429; called by muse, mutect2, varscan2
- PABPC1L | c.471C>T p.T157= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as rs1425932048, COSV99407580; called by muse, mutect2, varscan2
- PCDHB9 | c.1314C>T p.T438= | Silent (SNP) | VAF 87/304 reads (29%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.717C>T p.A239= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as COSV99533025; called by muse, mutect2, varscan2
- PFKP | c.969C>T p.S323= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV66900643; called by muse, mutect2, varscan2
- PHLDB1 | c.1305C>T p.T435= | Silent (SNP) | VAF 97/298 reads (33%) | catalogued as COSV100616329; called by muse, mutect2, varscan2
- PLEKHA4 | c.1405C>T p.L469= | Silent (SNP) | VAF 38/163 reads (23%) | catalogued as rs1476910737, COSV99612208; called by muse, mutect2, varscan2
- PLEKHO2 | c.1170C>T p.S390= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV100060579; called by muse, mutect2, varscan2
- POGLUT1 | c.270G>A p.Q90= | Silent (SNP) | VAF 67/258 reads (26%) | catalogued as COSV99809470; called by muse, varscan2
- PRAMEF18 | c.36G>A p.L12= | Silent (SNP) | VAF 52/460 reads (11%) | called by muse, varscan2
- PSG7 | c.1023C>T p.F341= | Silent (SNP) | VAF 78/340 reads (23%) | catalogued as rs140504359, COSV68447032; called by muse, mutect2, varscan2
- PSG9 | c.610C>T p.L204= | Silent (SNP) | VAF 148/620 reads (24%) | catalogued as rs568316162, COSV52483483, COSV99392107; called by muse, mutect2, varscan2
- PTGR2 | c.219C>T p.V73= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as rs561985906, COSV99966269; called by muse, mutect2, varscan2
- PTPN11 | c.33C>T p.I11= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV100692257; called by muse, mutect2, varscan2
- RASGEF1C | c.894C>T p.L298= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV100745673; called by muse, mutect2, varscan2
- RBM33 | c.660C>T p.F220= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1269634863, COSV55297865; called by muse, mutect2, varscan2
- RIMS4 | c.642T>A p.G214= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100865088; called by muse, mutect2, varscan2
- RYR1 | c.8664G>A p.R2888= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV100614910; called by muse, mutect2, varscan2
- SERPINB6 | c.870C>T p.L290= (on ENST00000612421 / NM_001271823.2; = p.L271= on NM_004568.6) | Silent (SNP) | VAF 102/435 reads (23%) | catalogued as COSV100177425; called by muse, mutect2, varscan2
- SIGLEC5 | c.516G>A p.A172= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1245923488, COSV55778747; called by muse, mutect2, varscan2
- SLAMF9 | c.777C>T p.V259= | Silent (SNP) | VAF 49/292 reads (17%) | catalogued as rs758816630, COSV63636430; called by muse, mutect2, varscan2
- SLC12A2 | c.1251C>T p.V417= | Silent (SNP) | VAF 61/243 reads (25%) | catalogued as rs750277953, COSV52468159, COSV99320673; called by muse, mutect2, varscan2
- SLC17A5 | c.405G>T p.G135= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as COSV100867008; called by muse, mutect2, varscan2
- SLC22A2 | c.99C>T p.F33= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs568261775, COSV65268498; called by muse, mutect2, varscan2
- SLC22A7 | c.345G>A p.Q115= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV101000775; called by muse, mutect2, varscan2
- SLC2A10 | c.1185C>T p.L395= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs371752807, COSV63716041; called by muse, mutect2, varscan2
- SLC2A5 | c.300G>A p.G100= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV101072626; called by muse, mutect2, varscan2
- SOCS6 | c.502C>T p.L168= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV101205666; called by muse, mutect2, varscan2
- SPATA17 | c.588A>G p.A196= | Silent (SNP) | VAF 37/197 reads (19%) | catalogued as COSV100860942; called by muse, mutect2, varscan2
- SPEG | c.4689G>A p.A1563= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1259965644, COSV100403557; called by muse, mutect2
- SPTB | c.2947C>T p.L983= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV67633220; called by muse, mutect2, varscan2
- SRCIN1 | c.3060C>T p.G1020= (on ENST00000621492; = p.G986= on NM_025248.3) | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- SRP68 | c.546C>T p.T182= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as COSV100325993; called by muse, mutect2, varscan2
- ST8SIA3 | c.642C>T p.I214= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV60653711; called by muse, mutect2, varscan2
- STK32A | c.279G>A p.E93= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100096724; called by muse, mutect2, varscan2
- SYT11 | c.630G>A p.V210= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as COSV100851283; called by muse, mutect2, varscan2
- TACC2 | c.243G>A p.R81= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs769522022, COSV100551785; called by muse, mutect2, varscan2
- TEAD3 | c.762G>A p.T254= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs576510878, COSV58818952; called by muse, mutect2, varscan2
- TENM3 | c.4104C>T p.I1368= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101304937; called by muse, mutect2, varscan2
- TLCD4 | c.312C>T p.S104= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as rs375141289, COSV64633531; called by muse, mutect2, varscan2
- TMEM217 | c.417C>T p.H139= | Silent (SNP) | VAF 66/273 reads (24%) | catalogued as COSV100362487; called by muse, mutect2, varscan2
- TMEM88 | c.63C>T p.P21= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99640878; called by muse, mutect2
- TNS1 | c.3816G>A p.L1272= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV50690851; called by muse, mutect2, varscan2
- TRHR | c.432G>A p.K144= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as COSV100304704; called by muse, mutect2, varscan2
- TRIM40 | c.631A>C p.R211= (on ENST00000376724; = p.R182= on NM_138700.4) | Silent (SNP) | VAF 63/229 reads (28%) | catalogued as COSV100325274; called by muse, mutect2, varscan2
- TSBP1 | c.1362G>A p.K454= (on ENST00000617061; = p.K459= on NM_006781.5) | Silent (SNP) | VAF 114/407 reads (28%) | catalogued as COSV100898727; called by muse, mutect2, varscan2
- TSHZ1 | c.3204G>A p.L1068= (on ENST00000580243 / NM_001308210.2; = p.L1023= on NM_005786.6) | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV100433456; called by muse, mutect2
- TSR3 | c.375C>T p.S125= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV99136143; called by muse, mutect2, varscan2
- TTN | c.50994G>A p.V16998= (on ENST00000591111; = p.V9574= on NM_003319.4) | Silent (SNP) | VAF 63/264 reads (24%) | catalogued as rs1247823850, COSV60452511; called by muse, mutect2, varscan2
- TTN | c.31677C>T p.L10559= (on ENST00000591111; = p.L9632= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV100599056; called by muse, mutect2, varscan2
- TTN | c.22440C>T p.F7480= (on ENST00000591111; = p.F6553= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs754815317, COSV59933248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTPAL | c.261C>T p.A87= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs1230386549, COSV99375356; called by muse, mutect2, varscan2
- TUBGCP2 | c.2352C>T p.T784= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs112980465, COSV53303824; called by muse, mutect2, varscan2
- UBA52 | c.108C>T p.I36= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV99723622; called by muse, mutect2, varscan2
- VPS18 | c.1860G>A p.R620= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as COSV99592331; called by muse, mutect2, varscan2
- VSIG2 | c.213C>T p.S71= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as COSV99423095; called by muse, mutect2, varscan2
- VWC2L | c.360G>A p.G120= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs267599196, COSV56966796; called by muse, mutect2, varscan2
- WFS1 | c.1242C>T p.F414= | Silent (SNP) | VAF 86/321 reads (27%) | catalogued as rs376646736, COSV56990179; ClinVar: likely benign; called by muse, mutect2, varscan2
- XDH | c.924G>A p.V308= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV101052078; called by muse, mutect2, varscan2
- ZFHX4 | c.6744C>T p.N2248= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs746985510, COSV51499099, COSV99258390; called by muse, mutect2, varscan2
- ZNF415 | c.591C>T p.F197= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV54699360; called by muse, mutect2, varscan2
- ZNF653 | c.1827C>T p.H609= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1392202792, COSV99542035; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95665072 G>A | 3'Flank (SNP) | VAF 8/32 reads (25%) | catalogued as rs1315418579; called by muse, mutect2, varscan2
- CNGA1 | c.-10G>A | 5'UTR (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100652159, COSV62053367; called by muse, mutect2, varscan2
- CPLANE1 | c.*3195C>T | 3'UTR (SNP) | VAF 24/122 reads (20%) | catalogued as rs750696838, COSV57063432; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEPACAM2 | c.80-17C>T | Intron (SNP) | VAF 44/175 reads (25%) | catalogued as COSV59062386; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.22C>T | RNA (SNP) | VAF 76/275 reads (28%) | catalogued as rs756651708; called by muse, mutect2, varscan2
- MIR520A | n.16T>C | RNA (SNP) | VAF 113/387 reads (29%) | catalogued as rs1172516897; called by muse, mutect2, varscan2
- NACA | c.71-4222C>T | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100771127; called by muse, mutect2, varscan2
- NFASC | c.3290-160C>T | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2
- NFASC | c.3290-159C>T | Intron (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- SNORD115-38 | n.55C>T | RNA (SNP) | VAF 154/609 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10361-5316C>T | Intron (SNP) | VAF 34/131 reads (26%) | catalogued as COSV100599058; called by muse, mutect2, varscan2
- TTN | c.10360+4114G>A | Intron (SNP) | VAF 29/94 reads (31%) | catalogued as COSV59933745, COSV60132056; called by muse, mutect2, varscan2
- TTN | c.10360+2137G>A | Intron (SNP) | VAF 56/244 reads (23%) | catalogued as rs1162467586, COSV100599061, COSV60393455; called by muse, mutect2, varscan2
